Somatic mutation profile of tumor specimen C3N-01852-04 (aliquot CPT0182500006) from CPTAC case C3N-01852, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.9 years (21,869 days).
Specimen C3N-01852-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36c107ac-6f8e-4a26-b9d2-06f81ebc13ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01852-31 (Blood Derived Normal), aliquot CPT0182540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd2033d8-e887-4b17-af47-f7a580b883d8

The open-access MAF lists 76 somatic variants for this specimen: 53 protein-altering or splice-affecting, 16 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 16, Frame Shift Del 5, RNA 3, 3'UTR 2, Intron 1, Splice Region 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 1746/7702 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AGBL1 | c.3139G>A p.A1047T | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as rs777333054, COSV66859300; called by muse, mutect2, varscan2
- ATP10A | c.2005G>A p.G669S | Missense Mutation (SNP) | VAF 133/394 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.153); catalogued as rs779668665; called by muse, mutect2, varscan2
- CAMP | c.43C>T p.R15W (on ENST00000296435; = p.R12W on NM_004345.5) | Missense Mutation (SNP) | VAF 116/325 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.721); catalogued as rs372010848; called by muse, mutect2, varscan2
- COL6A2 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 104/240 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.278); catalogued as rs376291264; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A5 | c.7249G>A p.E2417K (on ENST00000312481; = p.E2413K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.721); catalogued as rs368502118; called by muse, mutect2, varscan2
- CYP2B6 | c.1312G>T p.G438C | Missense Mutation (SNP) | VAF 155/654 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57843497; called by muse, mutect2, varscan2
- DCAF4 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs140598805; called by muse, mutect2, varscan2
- DSG3 | c.334A>G p.T112A | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752815998; called by muse, mutect2, varscan2
- E2F7 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 96/271 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs770647288, COSV59743844; called by muse, mutect2, varscan2
- EGFR | c.1934C>G p.S645C | Missense Mutation (SNP) | VAF 4064/8917 reads (46%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as rs772046081, COSV51772147; called by muse, mutect2, varscan2
- FAT1 | c.9382G>A p.D3128N | Missense Mutation (SNP) | VAF 125/339 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.155); catalogued as rs557987151; called by muse, mutect2, varscan2
- FLG | c.12137C>T p.S4046L | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs752715330, COSV64241792; called by muse, mutect2, varscan2
- FRAS1 | c.9238C>T p.R3080C | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190259271, COSV53599919; called by muse, mutect2, varscan2
- GNGT1 | c.-11-6C>A | Splice Region (SNP) | VAF 38/213 reads (18%) | catalogued as rs1200518544; called by muse, mutect2, varscan2
- HEATR5B | c.4550T>C p.I1517T | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs757905013; called by muse, mutect2, varscan2
- HOOK3 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs777110373, COSV56879587; called by muse, mutect2, varscan2
- HOXD1 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 37/478 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.03); catalogued as COSV100514121, COSV58923754; called by muse, mutect2
- KBTBD4 | c.206T>G p.F69C | Missense Mutation (SNP) | VAF 58/280 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs201795704; called by mutect2, varscan2
- KIAA1549L | c.4048G>A p.A1350T (on ENST00000321505; = p.A1647T on NM_012194.3) | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.667); catalogued as rs758860156, COSV58584697; called by muse, mutect2, varscan2
- MYH13 | c.2897C>T p.T966M | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs775127686; called by muse, mutect2, varscan2
- NOS1 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 87/232 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs913433943, COSV57609864; called by muse, mutect2, varscan2
- OR5M10 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs377738338; called by muse, mutect2, varscan2
- PCDHA11 | c.1898C>T p.T633M | Missense Mutation (SNP) | VAF 111/284 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV56501502, COSV56551821; called by muse, mutect2, varscan2
- PCSK2 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 210/770 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287184967, COSV52737337; called by muse, mutect2, varscan2
- PGBD4 | c.1750A>T p.N584Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.182); catalogued as rs748865965; called by muse, mutect2, varscan2
- PKHD1 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 97/306 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs1375765328, CM153184, COSV61884376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP4R3C | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 57/76 reads (75%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs778716151, COSV69080797; called by muse, mutect2, varscan2
- SLC25A52 | c.229G>T p.D77Y (on ENST00000672005; = p.D67Y on NM_001034172.4) | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV52502096; called by muse, mutect2, varscan2
- SSTR5 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755192712; called by muse, mutect2, varscan2
- TMC8 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 210/548 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs772173417; called by muse, mutect2, varscan2
- WNK1 | c.2851C>T p.P951S | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as rs1431038794; called by muse, mutect2, varscan2
- ZNF556 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 83/395 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751556137, COSV56911753; called by muse, mutect2, varscan2
- ZNF860 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs752530277, COSV100824437; called by muse, varscan2
- ARHGEF15 | c.2195T>C p.M732T | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- CHRM2 | c.524del p.E175Gfs*25 | Frame Shift Del (DEL) | VAF 108/370 reads (29%) | called by mutect2, pindel, varscan2
- DNAH5 | c.5576C>A p.T1859N | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- DOK2 | c.719A>T p.E240V | Missense Mutation (SNP) | VAF 157/356 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ERBB3 | c.2667_2670del p.H890Rfs*9 | Frame Shift Del (DEL) | VAF 40/202 reads (20%) | called by mutect2, pindel, varscan2
- HNMT | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTN3 | c.1267+5_1267+8del p.X423_splice | Splice Site (DEL) | VAF 14/62 reads (23%) | called by pindel, varscan2
- PDZD2 | c.3369G>C p.R1123S | Missense Mutation (SNP) | VAF 116/303 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- PIK3CA | c.1122_1123del p.R375Sfs*10 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | called by mutect2, pindel, varscan2
- PIK3CD | c.2512C>G p.Q838E | Missense Mutation (SNP) | VAF 254/691 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPFIBP1 | c.819del p.E274Kfs*7 (on ENST00000318304 / NM_177444.3; = p.E243Kfs*7 on NM_003622.4) | Frame Shift Del (DEL) | VAF 74/212 reads (35%) | called by mutect2, pindel, varscan2
- RIMS1 | c.1645G>T p.V549L | Missense Mutation (SNP) | VAF 104/298 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SPIC | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 107/256 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- SUPT20H | c.786G>C p.R262S (on ENST00000350612 / NM_001014286.3; = p.R263S on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- THSD7B | c.1838G>C p.C613S | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM33 | c.1065C>A p.N355K | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZBTB46 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 88/283 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF729 | c.1790del p.E597Gfs*24 | Frame Shift Del (DEL) | VAF 72/315 reads (23%) | called by mutect2, pindel, varscan2
- ZNF98 | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by mutect2, varscan2
- ARHGAP45 | c.2079C>T p.H693= | Silent (SNP) | VAF 85/360 reads (24%) | catalogued as rs149442520; called by muse, mutect2, varscan2
- CAMSAP3 | c.3666C>T p.S1222= | Silent (SNP) | VAF 71/326 reads (22%) | catalogued as rs779412443, COSV50347654; called by muse, mutect2, varscan2
- DNAH6 | c.9096C>T p.I3032= | Silent (SNP) | VAF 95/256 reads (37%) | catalogued as rs1297303162, COSV52890826, COSV99406445; called by muse, mutect2, varscan2
- DPT | c.102C>T p.S34= | Silent (SNP) | VAF 138/395 reads (35%) | catalogued as rs550327408; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNH1 | c.246A>G p.K82= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as COSV55074885; called by muse, mutect2, varscan2
- KCP | c.3439C>A p.R1147= (on ENST00000620378; = p.R1271= on NM_001366122.1) | Silent (SNP) | VAF 65/99 reads (66%) | called by muse, mutect2, varscan2
- KLF17 | c.66G>A p.A22= | Silent (SNP) | VAF 65/190 reads (34%) | catalogued as rs1342199027, COSV100955019, COSV64856703; called by muse, mutect2, varscan2
- MBD1 | c.1545C>A p.V515= (on ENST00000269468 / NM_001323950.1; = p.V459= on NM_015844.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 270/695 reads (39%) | called by muse, mutect2, varscan2
- MICAL3 | c.366C>T p.S122= | Silent (SNP) | VAF 131/355 reads (37%) | catalogued as rs1296561535; called by muse, mutect2, varscan2
- MYLK | c.1323A>G p.P441= | Silent (SNP) | VAF 79/436 reads (18%) | called by muse, mutect2, varscan2
- NME5 | c.165T>C p.S55= | Silent (SNP) | VAF 52/207 reads (25%) | called by muse, mutect2, varscan2
- NRTN | c.52C>T p.L18= | Silent (SNP) | VAF 230/898 reads (26%) | catalogued as rs1212676150; called by muse, mutect2, varscan2
- OR10G4 | c.624C>A p.G208= | Silent (SNP) | VAF 61/203 reads (30%) | catalogued as COSV100304655, COSV57978564; called by muse, mutect2, varscan2
- OR2T12 | c.501C>T p.C167= | Silent (SNP) | VAF 18/327 reads (6%) | catalogued as rs144239623; called by muse, mutect2
- TCTEX1D4 | c.651G>C p.G217= | Silent (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- XRN1 | c.4191C>T p.P1397= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs766209491; called by muse, mutect2, varscan2
- ANKRD20A5P | n.135C>T | RNA (SNP) | VAF 44/295 reads (15%) | called by muse, mutect2, varscan2
- CFI | c.*10C>G | 3'UTR (SNP) | VAF 72/124 reads (58%) | called by muse, mutect2, varscan2
- DERA | chr12:15911320 G>T | 5'Flank (SNP) | VAF 41/224 reads (18%) | called by muse, mutect2, varscan2
- EYS | c.1767-7750C>A | Intron (SNP) | VAF 12/45 reads (27%) | catalogued as rs970692410; called by mutect2, varscan2
- GVINP1 | n.6286A>T | RNA (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- MYADML | n.496C>T | RNA (SNP) | VAF 24/63 reads (38%) | catalogued as rs760279096; called by muse, mutect2, varscan2
- TP53TG3D | c.*451G>A | 3'UTR (SNP) | VAF 53/219 reads (24%) | catalogued as rs766223453; called by muse, mutect2, varscan2
